Somatic mutation profile of tumor specimen TCGA-60-2720-01A (aliquot TCGA-60-2720-01A-01D-1522-08) from TCGA case TCGA-60-2720, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 60.9 years (22,238 days).
Specimen TCGA-60-2720-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f10f372e-b9ef-4ffb-8f85-2351d478c6d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2720-11A (Solid Tissue Normal), aliquot TCGA-60-2720-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cd1c4ae-83fe-4e4c-88b3-fde2af8b5c0b

The open-access MAF lists 467 somatic variants for this specimen: 361 protein-altering or splice-affecting, 89 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 314, Silent 89, Nonsense Mutation 26, Splice Site 9, Frame Shift Del 8, Intron 7, RNA 4, 3'UTR 2, Splice Region 2, 5'Flank 2, 3'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN1A | c.1199T>A p.M400K | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs794726725, CM1511757, COSV57691480; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.6163A>T p.T2055S (on ENST00000614293; = p.T2025S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as COSV55807658; called by muse, mutect2, varscan2
- ABCC2 | c.3247A>T p.R1083W | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64988961; called by muse, mutect2, varscan2
- ACIN1 | c.344C>G p.S115* | Nonsense Mutation (SNP) | VAF 17/158 reads (11%) | catalogued as COSV52983117; called by muse, mutect2, varscan2
- ACKR4 | c.842T>C p.M281T | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs546618608, COSV51443650; called by muse, mutect2
- ADAMTS20 | c.4060T>A p.C1354S | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67141085; called by muse, mutect2, varscan2
- ADAR | c.850A>G p.T284A | Missense Mutation (SNP) | VAF 46/320 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52722373; called by muse, mutect2, varscan2
- ADAT1 | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.462); catalogued as COSV57189132; called by muse, mutect2, varscan2
- ADGRG4 | c.4153G>T p.A1385S | Missense Mutation (SNP) | VAF 37/437 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV54969271; called by muse, mutect2
- ADGRL2 | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 15/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54693505; called by muse, mutect2
- AGPAT2 | c.134C>G p.S45W | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.898); catalogued as CM164199, COSV100865176; called by muse, mutect2, varscan2
- AHCTF1 | c.3811G>C p.E1271Q (on ENST00000366508; = p.E1245Q on NM_015446.5) | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV58256918; called by muse, mutect2
- AK9 | c.5153G>C p.R1718P | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.706); catalogued as COSV69853828; called by muse, mutect2
- AKAP9 | c.1738G>C p.E580Q | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62359536; called by muse, mutect2, varscan2
- ALDH1A2 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs572439325, COSV51087224; called by muse, mutect2, varscan2
- ALPK2 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 15/399 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as rs1293644043, COSV64498110; called by muse, mutect2
- AMER1 | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV57670532; called by muse, mutect2
- AMER3 | c.980C>A p.P327Q | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as rs983772806, COSV100367006; called by muse, mutect2, varscan2
- AMPD3 | c.1018G>C p.E340Q (on ENST00000396553 / NM_001025389.2; = p.E349Q on NM_000480.3) | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as COSV67332935; called by muse, mutect2, varscan2
- ANKRD12 | c.1618A>T p.T540S | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as COSV50856529; called by muse, mutect2
- ANO3 | c.2027G>T p.R676L | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as COSV56811736, COSV99886535; called by muse, mutect2, varscan2
- ANO3 | c.2718C>A p.Y906* | Nonsense Mutation (SNP) | VAF 43/249 reads (17%) | catalogued as COSV56811780; called by muse, mutect2, varscan2
- AOX1 | c.2444G>C p.G815A | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV65984679; called by muse, mutect2, varscan2
- APEX2 | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); catalogued as COSV66624595; called by muse, mutect2, varscan2
- APOB | c.11365G>A p.V3789I | Missense Mutation (SNP) | VAF 58/325 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.065); catalogued as rs752262589, COSV51956573; called by muse, mutect2, varscan2
- ARHGAP29 | c.3147G>C p.K1049N | Missense Mutation (SNP) | VAF 23/291 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV53118092; called by muse, mutect2
- ARID1A | c.3662T>C p.M1221T | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.258); catalogued as rs1306136331, COSV100253935, COSV61390768; called by muse, mutect2, varscan2
- ARMCX3 | c.520A>T p.T174S | Missense Mutation (SNP) | VAF 27/309 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.089); catalogued as COSV57871887; called by muse, mutect2
- ART4 | c.706G>A p.V236I | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.401); catalogued as rs768235727, COSV57453536; called by muse, mutect2, varscan2
- ASAH2 | c.58A>T p.M20L | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.01); catalogued as COSV61484573; called by muse, mutect2, varscan2
- ASB11 | c.491C>A p.A164D | Missense Mutation (SNP) | VAF 31/368 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.855); catalogued as COSV60356777, COSV60356813; called by muse, mutect2
- ASB12 | c.27G>C p.K9N | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV62856845, COSV62857964; called by muse, mutect2
- ASH1L | c.5203G>C p.D1735H | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.443); catalogued as COSV64214833; called by muse, mutect2
- ASPHD2 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1450597703, COSV53221267; called by muse, mutect2, varscan2
- ATP13A3 | c.538A>G p.T180A | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV55470334; called by muse, mutect2, varscan2
- ATRX | c.3911G>T p.G1304V | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV64885361; called by muse, mutect2
- ATRX | c.2576G>T p.G859V | Missense Mutation (SNP) | VAF 87/948 reads (9%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as COSV64875552, COSV64885373; called by muse, mutect2
- ATRX | c.2090A>G p.K697R | Missense Mutation (SNP) | VAF 36/556 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV64885385; called by muse, mutect2
- BCORL1 | c.1929del p.M644Cfs*4 | Frame Shift Del (DEL) | VAF 23/146 reads (16%) | catalogued as rs1229639561; called by mutect2, pindel, varscan2
- BDH1 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs1282029108, COSV64020143; called by muse, mutect2
- BIRC6 | c.13827G>C p.M4609I | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV70207431; called by muse, mutect2
- BMP15 | c.625T>G p.C209G | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV53142309; called by muse, mutect2
- BOLL | c.484C>A p.R162S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.023); catalogued as rs753383912, COSV56577996; called by muse, mutect2, varscan2
- BORCS6 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV66505669; called by muse, mutect2, varscan2
- BPI | c.1156C>A p.L386I (on ENST00000262865; = p.L382I on NM_001725.3) | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); catalogued as COSV99481047; called by muse, mutect2
- BPIFA1 | c.50C>A p.T17N | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs769038767, COSV62825379; called by muse, mutect2, varscan2
- BPIFB6 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 22/145 reads (15%) | catalogued as COSV62756956, COSV62757557; called by muse, mutect2, varscan2
- BRD1 | c.520A>T p.K174* | Nonsense Mutation (SNP) | VAF 14/99 reads (14%) | catalogued as COSV53462528; called by muse, mutect2
- BRINP2 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100838534, COSV64180929; called by muse, mutect2
- BTNL8 | c.1388C>A p.T463N | Missense Mutation (SNP) | VAF 50/308 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as COSV51462517; called by muse, mutect2, varscan2
- C16orf78 | c.722A>T p.D241V | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54557705; called by muse, mutect2, varscan2
- C1orf56 | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV54849426; called by muse, mutect2, varscan2
- C2CD6 | c.1335G>C p.L445F | Missense Mutation (SNP) | VAF 58/329 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV53801485; called by muse, mutect2, varscan2
- C5orf22 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.258); catalogued as COSV57600171; called by muse, mutect2
- C6 | c.2021C>A p.T674N | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.257); catalogued as COSV54711052, COSV54720684; called by muse, mutect2, varscan2
- CA6 | c.339C>A p.H113Q | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66263209; called by muse, mutect2, varscan2
- CACNA1F | c.4704G>T p.E1568D | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV59907375; called by muse, mutect2
- CACNA2D2 | c.2656G>C p.E886Q (on ENST00000479441 / NM_001174051.3; = p.E879Q on NM_006030.4) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.372); catalogued as COSV56570097; called by muse, mutect2, varscan2
- CATSPER2 | c.1571A>C p.N524T (on ENST00000321596 / NM_001282309.3; = p.N526T on NM_172095.4) | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV58662107; called by muse, mutect2, varscan2
- CCDC110 | c.2431C>G p.Q811E | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV56873845; called by muse, mutect2, varscan2
- CCDC110 | c.1303C>A p.L435I | Missense Mutation (SNP) | VAF 39/271 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56873855; called by muse, mutect2, varscan2
- CCDC22 | c.1525G>T p.E509* | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | catalogued as COSV66052173; called by muse, mutect2
- CCDC88A | c.1657-1G>C p.X553_splice | Splice Site (SNP) | VAF 10/53 reads (19%) | catalogued as rs766805702, COSV55071298; called by muse, mutect2, varscan2
- CCL20 | c.235C>A p.Q79K | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62591810; called by muse, mutect2, varscan2
- CDC5L | c.2036G>T p.R679L | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.879); catalogued as COSV101014958, COSV101015256; called by muse, mutect2, varscan2
- CDH10 | c.40del p.V14Yfs*11 | Frame Shift Del (DEL) | VAF 24/227 reads (11%) | catalogued as COSV100051611; called by mutect2, pindel, varscan2
- CEP135 | c.1560A>T p.E520D | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV57263333; called by muse, varscan2
- CEP192 | c.7105G>C p.E2369Q | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV58071752; called by muse, mutect2, varscan2
- CFH | c.3249G>T p.M1083I | Missense Mutation (SNP) | VAF 31/399 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV100808468, COSV66414597; called by muse, mutect2
- CFHR4 | c.1102G>T p.A368S (on ENST00000367416 / NM_001201551.2; = p.A122S on NM_006684.5) | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.388); catalogued as rs1213820697, COSV52236825; called by muse, varscan2
- CHODL | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100167155; called by muse, mutect2, varscan2
- CLPSL1 | c.306C>G p.I102M | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV65815170; called by muse, mutect2
- CLTRN | c.318-1G>C p.X106_splice | Splice Site (SNP) | VAF 16/240 reads (7%) | catalogued as COSV66712553; called by muse, mutect2
- CLVS1 | c.369C>G p.I123M | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV57971814, COSV57984735; called by muse, mutect2, varscan2
- CMTM3 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV62680487; called by muse, mutect2, varscan2
- CNGA2 | c.430C>A p.L144I | Missense Mutation (SNP) | VAF 39/375 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV61706574; called by muse, mutect2, varscan2
- COL11A1 | c.5392G>A p.E1798K | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.67); catalogued as COSV62201314; called by muse, mutect2, varscan2
- COL11A1 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs747054416, COSV62201325; called by muse, mutect2, varscan2
- COL12A1 | c.2759C>T p.S920L | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.405); catalogued as COSV59410282; called by muse, mutect2, varscan2
- COL22A1 | c.3870G>A p.R1290= | Splice Region (SNP) | VAF 43/141 reads (30%) | catalogued as COSV57364908; called by muse, mutect2, varscan2
- COL5A2 | c.2806G>T p.G936W | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100879956; called by muse, mutect2, varscan2
- COL9A1 | c.1129C>A p.R377S | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.897); catalogued as COSV57878516; called by muse, mutect2, varscan2
- CPED1 | c.2486C>T p.S829L | Missense Mutation (SNP) | VAF 44/296 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.433); catalogued as rs774595481, COSV60015146; called by muse, mutect2, varscan2
- CPN1 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1452212991, COSV64942028, COSV64942894; called by muse, mutect2, varscan2
- CPS1 | c.2198C>T p.P733L | Missense Mutation (SNP) | VAF 19/203 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV51805606, COSV51827074; called by muse, mutect2
- CPT1B | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 30/267 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.125); catalogued as COSV56419432; called by muse, mutect2, varscan2
- CRACD | c.592G>C p.G198R | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51733762; called by muse, mutect2, varscan2
- CSPG4 | c.1361C>G p.P454R | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57902700; called by muse, varscan2
- CYC1 | c.653A>T p.Y218F | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59645261; called by muse, mutect2
- CYLC1 | c.716C>G p.S239* | Nonsense Mutation (SNP) | VAF 17/81 reads (21%) | catalogued as COSV61411943, COSV61412298, COSV61416610; called by muse, mutect2, varscan2
- CYP2D6 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV62245863; called by muse, mutect2
- CYP3A4 | c.1368C>A p.D456E (on ENST00000336411; = p.D425E on NM_017460.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/447 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60504622; called by muse, mutect2, varscan2
- DACH2 | c.694A>G p.M232V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV64188814; called by muse, mutect2, varscan2
- DCDC1 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 56/412 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.069); catalogued as COSV60861867; called by muse, mutect2, varscan2
- DDX53 | c.213A>G p.I71M | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV60070212; called by muse, mutect2
- DEFB112 | c.101C>G p.S34* | Nonsense Mutation (SNP) | VAF 26/209 reads (12%) | catalogued as COSV59182873, COSV59183219; called by muse, mutect2, varscan2
- DLL4 | c.1337G>T p.R446L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.565); catalogued as COSV51061089, COSV51074572; called by muse, mutect2
- DNAH11 | c.2913T>A p.D971E | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.779); catalogued as COSV60986660; called by muse, mutect2
- DNAH5 | c.9966C>G p.I3322M | Missense Mutation (SNP) | VAF 85/279 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54257649; called by muse, mutect2, varscan2
- DNAH5 | c.660+1G>A p.X220_splice | Splice Site (SNP) | VAF 8/97 reads (8%) | catalogued as COSV54257657; called by muse, mutect2
- DNASE1L1 | c.774+1G>T p.X258_splice | Splice Site (SNP) | VAF 8/116 reads (7%) | catalogued as rs1557187211, COSV50011461; called by muse, mutect2
- DNASE1L1 | c.774G>T p.E258D | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV50011472; called by muse, mutect2
- DNER | c.586-1G>T p.X196_splice | Splice Site (SNP) | VAF 10/61 reads (16%) | catalogued as COSV59173701; called by muse, mutect2
- DOCK11 | c.5914G>T p.A1972S | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.021); catalogued as COSV52249268; called by muse, mutect2, varscan2
- DOCK7 | c.1425+1G>T p.X475_splice | Splice Site (SNP) | VAF 33/245 reads (13%) | catalogued as rs1003102091, COSV52024005; called by muse, mutect2, varscan2
- DPY19L4 | c.385A>T p.K129* | Nonsense Mutation (SNP) | VAF 62/193 reads (32%) | catalogued as COSV68963994; called by muse, mutect2, varscan2
- DPYSL5 | c.889G>A p.V297M | Missense Mutation (SNP) | VAF 77/499 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV56517200; called by muse, mutect2, varscan2
- DUS3L | c.1878C>G p.I626M | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1276289143, COSV57833937; called by muse, mutect2, varscan2
- DZANK1 | c.1463C>G p.S488C (on ENST00000262547 / NM_001099407.1; = p.S295C on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52758189; called by muse, mutect2, varscan2
- ELF1 | c.461A>T p.Q154L | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.063); catalogued as COSV53503579; called by muse, mutect2, varscan2
- ELOVL3 | c.110C>G p.S37* | Nonsense Mutation (SNP) | VAF 36/359 reads (10%) | catalogued as COSV100892769, COSV64175136; called by muse, mutect2
- EPB41L3 | c.1233G>T p.R411S | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59470890; called by muse, mutect2, varscan2
- EPB41L4B | c.1588G>C p.E530Q | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.13); catalogued as COSV65805319; called by muse, mutect2, varscan2
- EPRS1 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 30/334 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV100859301, COSV65102011; called by muse, mutect2
- EXD3 | c.1051G>C p.D351H | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.187); catalogued as COSV59814666; called by muse, mutect2, varscan2
- EXOSC10 | c.516C>G p.F172L | Missense Mutation (SNP) | VAF 38/272 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV58663657, COSV58668039, COSV58668567; called by muse, varscan2
- FBXL18 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66669190; called by muse, mutect2, varscan2
- FCRL2 | c.457G>T p.G153W | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as rs777986999, COSV100830031; called by muse, mutect2, varscan2
- FFAR4 | c.247T>G p.C83G | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65179982; called by muse, mutect2, varscan2
- FLRT2 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 76/351 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV58150869; called by muse, mutect2, varscan2
- FOLH1 | c.2083A>G p.S695G | Missense Mutation (SNP) | VAF 87/300 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV57058038; called by muse, mutect2, varscan2
- FOLH1 | c.1564G>C p.E522Q | Missense Mutation (SNP) | VAF 38/303 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.711); catalogued as COSV57058049; called by muse, mutect2, varscan2
- FOXC1 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV66516854; called by muse, mutect2, varscan2
- FOXO4 | c.527C>G p.S176C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV58576624; called by muse, mutect2, varscan2
- FRG2C | c.137C>A p.T46N | Missense Mutation (SNP) | VAF 20/534 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV57312891; called by muse, mutect2
- FRMPD3 | c.2896C>A p.L966M | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.009); catalogued as COSV99347341; called by muse, mutect2, varscan2
- FRYL | c.2902G>C p.E968Q | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV51964643; called by muse, mutect2
- FTMT | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 15/92 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.447); catalogued as COSV58421672; called by muse, mutect2, varscan2
- FXN | c.400G>C p.D134H (on ENST00000377270; = p.D209H on NM_000144.5) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV66009683; called by muse, mutect2, varscan2
- G6PC | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 23/134 reads (17%) | catalogued as COSV53833142; called by muse, mutect2, varscan2
- GAREM1 | c.877C>T p.L293F | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.543); catalogued as rs1276317247, COSV52516939; called by muse, mutect2, varscan2
- GCC1 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV50002247; called by muse, mutect2, varscan2
- GDF2 | c.1197C>A p.S399R | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs1555209089; called by muse, varscan2
- GNL3L | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60577889; called by muse, mutect2
- GPAT3 | c.1125+1G>C p.X375_splice | Splice Site (SNP) | VAF 18/108 reads (17%) | catalogued as COSV52360211; called by muse, mutect2, varscan2
- GPKOW | c.773A>G p.Y258C | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50243726, COSV50246022; called by muse, mutect2
- GRM3 | c.2101G>T p.V701L | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs753535059, COSV64480947; called by muse, mutect2
- GULP1 | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV63067753, COSV63068504, COSV63076261; called by muse, mutect2, varscan2
- H2BC8 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV55126416, COSV55128045, COSV99773107; called by muse, mutect2, varscan2
- HACE1 | c.2550G>T p.M850I | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.222); catalogued as COSV99494413; called by muse, mutect2, varscan2
- HBE1 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.917); catalogued as COSV53081578; called by muse, mutect2
- HCAR3 | c.316A>T p.M106L | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.401); catalogued as COSV63678610; called by muse, mutect2, varscan2
- HCN1 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as COSV57495620, COSV57543783; called by muse, mutect2
- HCN4 | c.2425C>G p.P809A | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.762); catalogued as COSV56083229, COSV56088382; called by muse, mutect2, varscan2
- HELZ | c.1529del p.R510Pfs*18 | Frame Shift Del (DEL) | VAF 13/130 reads (10%) | catalogued as COSV62376342; called by mutect2, pindel, varscan2
- HERC2 | c.9930G>C p.K3310N | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV55353845; called by muse, mutect2, varscan2
- HHIPL2 | c.1547G>A p.G516D | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58567535; called by muse, mutect2, varscan2
- HIVEP3 | c.6802G>C p.E2268Q | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.795); catalogued as COSV56025481; called by muse, mutect2, varscan2
- HLA-C | c.958G>T p.V320F | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.993); catalogued as COSV66119775; called by muse, mutect2, varscan2
- HLCS | c.242C>G p.S81C | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.533); catalogued as COSV60799171; called by muse, mutect2
- HOXC12 | c.244A>T p.T82S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54535844; called by muse, mutect2
- IDH3A | c.563G>T p.R188L | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV100211075; called by muse, mutect2, varscan2
- IFNB1 | c.398C>T p.T133I | Missense Mutation (SNP) | VAF 63/382 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.895); catalogued as rs189255883, COSV66525767; called by muse, mutect2, varscan2
- IGKV6D-21 | c.236C>A p.S79* | Nonsense Mutation (SNP) | VAF 24/276 reads (9%) | catalogued as rs753016861; called by muse, mutect2
- IKBKE | c.907A>T p.S303C | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV65627236; called by muse, mutect2, varscan2
- IKZF4 | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56272282; called by muse, mutect2
- IL22 | c.330G>T p.R110S | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.29); catalogued as rs1438691184, COSV60160935; called by muse, mutect2, varscan2
- IMPG1 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.117); catalogued as COSV64062681; called by muse, mutect2, varscan2
- INPP4A | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50845665; called by muse, mutect2, varscan2
- IRF2BP1 | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56195512; called by muse, mutect2, varscan2
- ITGB8 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV56015535; called by muse, mutect2, varscan2
- ITIH4 | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.069); catalogued as COSV56579665; called by muse, mutect2, varscan2
- ITIH6 | c.3755G>T p.R1252L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV54492618, COSV54495825; called by muse, mutect2, varscan2
- ITIH6 | c.2980C>T p.P994S | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV54493954; called by muse, mutect2, varscan2
- JAG1 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 53/247 reads (21%) | catalogued as COSV54763920; called by muse, varscan2
- KAT6A | c.2629G>T p.E877* | Nonsense Mutation (SNP) | VAF 13/126 reads (10%) | catalogued as COSV55912726; called by muse, mutect2, varscan2
- KCNC3 | c.1112C>G p.P371R | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65388866; called by muse, mutect2, varscan2
- KCNH1 | c.1033G>T p.G345C (on ENST00000271751 / NM_172362.3; = p.G318C on NM_002238.4) | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV55108722; called by muse, mutect2, varscan2
- KCNH7 | c.1615A>T p.R539W | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59817002; called by muse, mutect2, varscan2
- KIF27 | c.2437A>G p.R813G | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV52831777; called by muse, mutect2, varscan2
- KIF2B | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1446522015, COSV52136576; called by muse, mutect2, varscan2
- KIR2DL3 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 112/1146 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV60897527, COSV60901429; called by muse, mutect2
- KLB | c.1166G>C p.G389A | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV57305724; called by muse, mutect2, varscan2
- KLHL13 | c.1545G>T p.W515C | Missense Mutation (SNP) | VAF 115/699 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53254034; called by muse, mutect2, varscan2
- KLHL41 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 60/344 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.917); catalogued as COSV52931921; called by muse, mutect2, varscan2
- KRT9 | c.867G>C p.K289N | Missense Mutation (SNP) | VAF 52/280 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV55855662, COSV55855843; called by muse, mutect2, varscan2
- KYAT3 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV53106532; called by muse, mutect2, varscan2
- LACRT | c.161C>A p.P54Q | Missense Mutation (SNP) | VAF 29/321 reads (9%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as COSV99143939; called by muse, mutect2
- LBP | c.113G>C p.G38A | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54144649; called by muse, mutect2, varscan2
- LILRB2 | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as COSV58748671; called by muse, mutect2, varscan2
- LIMK2 | c.901G>C p.E301Q | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.315); catalogued as COSV59185062; called by mutect2, varscan2
- LRGUK | c.285G>T p.M95I | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV53645015; called by muse, mutect2, varscan2
- LRP1 | c.5027G>A p.S1676N | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54529023; called by muse, mutect2, varscan2
- LRRC7 | c.368C>A p.P123Q (on ENST00000651989 / NM_001370785.2; = p.P90Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50652846; called by muse, mutect2, varscan2
- LTBP1 | c.623T>C p.V208A | Missense Mutation (SNP) | VAF 101/587 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as COSV63199195; called by muse, mutect2, varscan2
- LY6G5B | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.558); catalogued as rs1251115169, COSV65498339; called by muse, mutect2, varscan2
- MAGEA4 | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as rs199657597, COSV52343452; called by muse, mutect2, varscan2
- MAGEC1 | c.1744C>G p.Q582E | Missense Mutation (SNP) | VAF 170/997 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.585); catalogued as COSV53582826; called by muse, mutect2, varscan2
- MAGEE1 | c.2090G>T p.R697I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV63912513; called by muse, mutect2, varscan2
- MARCO | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1460374110; called by muse, mutect2
- MATN3 | c.988C>G p.H330D | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.744); catalogued as COSV68100306, COSV68100753; called by muse, mutect2, varscan2
- MCM5 | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV53348682; called by muse, mutect2
- MTREX | c.2650G>C p.D884H | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1217642299, COSV57930910; called by muse, mutect2, varscan2
- MUC16 | c.39576C>G p.F13192L | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.68); catalogued as COSV66697466; called by muse, mutect2, varscan2
- MYH1 | c.3394T>G p.S1132A | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56858650; called by muse, mutect2, varscan2
- MYH11 | c.5881C>G p.R1961G | Missense Mutation (SNP) | VAF 55/247 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs772155686, COSV55572962; called by muse, mutect2, varscan2
- MYH4 | c.3945G>C p.Q1315H | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV55114694, COSV55127841; called by muse, mutect2, varscan2
- MYO1E | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 18/86 reads (21%) | catalogued as COSV55697294; called by muse, mutect2, varscan2
- MYOM3 | c.2909C>G p.S970* | Nonsense Mutation (SNP) | VAF 24/122 reads (20%) | catalogued as COSV58402252; called by muse, varscan2
- NAV3 | c.4124C>A p.S1375Y | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57117275; called by muse, mutect2, varscan2
- NCAPG2 | c.1835C>T p.S612L | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as COSV51992589; called by muse, mutect2, varscan2
- NELL1 | c.2006C>G p.T669R | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0.015); catalogued as COSV54335946; called by muse, mutect2, varscan2
- NES | c.2424G>C p.K808N | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as COSV63963337; called by muse, mutect2, varscan2
- NLRP8 | c.2876+1G>C p.X959_splice | Splice Site (SNP) | VAF 17/107 reads (16%) | catalogued as COSV52595197; called by muse, mutect2, varscan2
- NLRP9 | c.2593C>G p.H865D | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.145); catalogued as COSV60468591; called by muse, mutect2, varscan2
- NOP56 | c.1642G>C p.E548Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV61391960; called by muse, mutect2
- NOX3 | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50167518; called by muse, mutect2, varscan2
- NPY1R | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV56714916, COSV56716927; called by muse, mutect2, varscan2
- NRXN3 | c.652G>T p.G218C | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73587361; called by muse, mutect2, varscan2
- OR1C1 | c.307T>C p.F103L | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV101376295; called by muse, mutect2
- OR2M7 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 32/562 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV58741061; called by muse, mutect2
- OR2T1 | c.522C>A p.N174K | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV63543050; called by muse, mutect2, varscan2
- OR4A16 | c.23C>G p.T8R | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV59045410; called by muse, varscan2
- OR4K14 | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV59294562; called by muse, mutect2, varscan2
- OR52E4 | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV57626586; called by muse, mutect2, varscan2
- OR5R1 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV56573758; called by muse, mutect2, varscan2
- OR6C1 | c.807C>A p.S269R | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV65574668; called by muse, mutect2, varscan2
- OR6V1 | c.389A>T p.Y130F | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV69237727; called by muse, mutect2, varscan2
- P3H2 | c.693G>T p.R231S | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV60029096; called by muse, mutect2, varscan2
- PAPPA2 | c.2187C>A p.D729E | Missense Mutation (SNP) | VAF 37/277 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV62788380; called by muse, mutect2, varscan2
- PCDH15 | c.2368G>T p.V790L | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.365); catalogued as COSV57408605; called by muse, mutect2, varscan2
- PCDHA1 | c.832G>A p.V278I | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.045); catalogued as rs782409216, COSV65375342; called by muse, mutect2, varscan2
- PCDHA11 | c.1411T>A p.C471S | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.003); catalogued as COSV100255811; called by muse, mutect2, varscan2
- PCDHB12 | c.1343C>A p.A448D | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.466); catalogued as rs1432721338, COSV53401853; called by muse, mutect2, varscan2
- PCDHGB6 | c.2167A>G p.T723A | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV54051112; called by muse, mutect2, varscan2
- PDE11A | c.2414A>G p.D805G | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as rs763032610, COSV53711560; called by muse, mutect2, varscan2
- PFKFB1 | c.961G>C p.E321Q | Missense Mutation (SNP) | VAF 18/158 reads (11%) | PolyPhen possibly damaging (0.854); catalogued as COSV66629758; called by muse, mutect2, varscan2
- PGK2 | c.147C>A p.Y49* | Nonsense Mutation (SNP) | VAF 25/226 reads (11%) | catalogued as COSV59165947; called by muse, mutect2, varscan2
- PHF6 | c.742G>T p.G248C (on ENST00000332070 / NM_032458.3; = p.G249C on NM_032335.3) | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59707365; called by muse, mutect2, varscan2
- PHKA2 | c.2924C>G p.S975C | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV66056875; called by muse, mutect2, varscan2
- PIK3C3 | c.2357G>T p.G786V | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV56285676; called by muse, mutect2, varscan2
- PIN4 | c.212A>G p.E71G (on ENST00000664196; = p.E46G on NM_006223.4) | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54485789; called by muse, mutect2, varscan2
- PIWIL1 | c.1320C>A p.D440E | Missense Mutation (SNP) | VAF 40/360 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55352850; called by muse, mutect2, varscan2
- PKHD1 | c.736A>G p.I246V | Missense Mutation (SNP) | VAF 27/266 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs776726642, COSV61897903; called by muse, mutect2
- PKHD1L1 | c.8203G>T p.G2735C | Missense Mutation (SNP) | VAF 63/267 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV65755549; called by muse, mutect2, varscan2
- PLXNA4 | c.265G>C p.D89H | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.726); catalogued as COSV58113377, COSV58165790; called by muse, mutect2
- PON1 | c.689C>A p.P230H | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV55934201; called by muse, varscan2
- PON1 | c.676A>T p.I226F | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55934208; called by muse, varscan2
- PPRC1 | c.488C>G p.S163C | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53389240; called by muse, mutect2, varscan2
- PREX2 | c.1125G>T p.W375C | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs1368451095, COSV55804134; called by muse, mutect2, varscan2
- PRLR | c.322C>A p.Q108K | Missense Mutation (SNP) | VAF 173/555 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV51501401; called by muse, mutect2, varscan2
- PRMT6 | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV63656562; called by muse, mutect2, varscan2
- PTCH2 | c.237G>C p.E79D | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV64711109; called by muse, mutect2, varscan2
- PTGER3 | c.121C>G p.P41A | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1328620495, COSV100138498, COSV60699163; called by muse, mutect2
- PTPRT | c.3712G>C p.D1238H | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62030235; called by muse, mutect2, varscan2
- PXDNL | c.2609C>G p.A870G | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62500656; called by muse, mutect2
- RANBP2 | c.1817G>T p.W606L | Missense Mutation (SNP) | VAF 35/290 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV99313590; called by muse, mutect2, varscan2
- RAP1A | c.333G>A p.M111I | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.148); catalogued as COSV62729597; called by muse, mutect2, varscan2
- RFX6 | c.863A>G p.Q288R | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV60589424; called by muse, mutect2, varscan2
- RGL4 | c.449T>C p.L150P | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.96); catalogued as COSV51945628; called by muse, mutect2, varscan2
- RHEBL1 | c.129C>G p.Y43* | Nonsense Mutation (SNP) | VAF 21/144 reads (15%) | catalogued as COSV56505095; called by muse, mutect2, varscan2
- RHOT1 | c.1451A>C p.E484A | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV61718632; called by muse, mutect2
- RIMS2 | c.1247G>T p.R416L (on ENST00000666250 / NM_001348490.2; = p.R224L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.794); catalogued as COSV51731900; called by muse, mutect2, varscan2
- RO60 | c.192G>T p.L64F | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV66475300; called by muse, mutect2, varscan2
- ROBO1 | c.3412T>C p.Y1138H | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as COSV71399306; called by muse, mutect2, varscan2
- RPAP2 | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV72101699; called by muse, mutect2, varscan2
- RPTN | c.1974C>A p.H658Q | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.36); catalogued as COSV60169577; called by muse, mutect2, varscan2
- RTL3 | c.997T>G p.C333G | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.81); catalogued as COSV58186269; called by muse, mutect2, varscan2
- RTL9 | c.745G>C p.A249P | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71826605; called by muse, varscan2
- RUBCN | c.578G>C p.R193T | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.632); catalogued as COSV56375807; called by muse, mutect2
- RXFP3 | c.1270C>A p.P424T | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV57508682; called by muse, mutect2, varscan2
- RYR1 | c.6339C>A p.S2113R | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV62113420; called by muse, mutect2, varscan2
- RYR2 | c.9645G>T p.M3215I | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV63677317; called by muse, mutect2, varscan2
- RYR2 | c.9646G>T p.E3216* | Nonsense Mutation (SNP) | VAF 30/237 reads (13%) | catalogued as COSV63664984, COSV63720106; called by muse, mutect2, varscan2
- SCML2 | c.779C>A p.A260E | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV52625705; called by muse, varscan2
- SCN2A | c.2099C>G p.S700* | Nonsense Mutation (SNP) | VAF 32/222 reads (14%) | catalogued as COSV51852927, COSV51858044; called by muse, mutect2, varscan2
- SEC24C | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 50/278 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as rs547378473, COSV59545573; called by muse, mutect2, varscan2
- SELENOT | c.562G>C p.D188H | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.445); catalogued as COSV71982339; called by muse, mutect2, varscan2
- SEMA3A | c.1033A>G p.M345V | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs1184272644, COSV54891984; called by muse, mutect2, varscan2
- SENP1 | c.1853G>C p.R618T | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV50309078; called by muse, mutect2, varscan2
- SH3BP4 | c.1193C>G p.S398* | Nonsense Mutation (SNP) | VAF 6/85 reads (7%) | catalogued as COSV60647017; called by muse, mutect2
- SHROOM4 | c.3176C>G p.S1059* | Nonsense Mutation (SNP) | VAF 11/112 reads (10%) | catalogued as COSV56798615; called by muse, mutect2, varscan2
- SHROOM4 | c.1646G>C p.G549A | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV56798626; called by muse, mutect2, varscan2
- SIX2 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100284182, COSV57392528; called by muse, mutect2, varscan2
- SLC16A2 | c.720C>A p.S240R | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52089680; called by muse, mutect2, varscan2
- SLC22A2 | c.1101G>C p.M367I | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV65268387; called by muse, mutect2
- SLC44A5 | c.861G>A p.W287* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | catalogued as rs1242509261, COSV63765026; called by muse, mutect2, varscan2
- SLC4A5 | c.1244A>G p.K415R | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.909); catalogued as COSV61033947; called by muse, mutect2, varscan2
- SLC8A1 | c.1310C>A p.T437N | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60498945; called by muse, mutect2, varscan2
- SLCO1B3 | c.1918T>C p.Y640H | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV53948089; called by muse, mutect2, varscan2
- SLIT2 | c.4348G>T p.E1450* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as rs762299174, COSV56599230; called by mutect2, varscan2
- SLIT2 | c.4348+1G>T p.X1450_splice | Splice Site (SNP) | VAF 4/26 reads (15%) | catalogued as COSV56599236; called by mutect2, varscan2
- SLIT3 | c.3121G>C p.E1041Q | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.511); catalogued as COSV60636598; called by muse, mutect2
- SLITRK1 | c.824C>G p.P275R | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.814); catalogued as COSV101000035, COSV65678040; called by muse, mutect2, varscan2
- SLITRK3 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 50/326 reads (15%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.998); catalogued as rs1159700109, COSV53854422, COSV99579204; called by muse, mutect2, varscan2
- SOS1 | c.1249C>G p.L417V | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV67678039; called by muse, mutect2, varscan2
- SPANXN5 | c.84G>C p.E28D | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV64968910; called by muse, mutect2
- SPTA1 | c.4003C>G p.R1335G | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV63754837, COSV63760532; called by muse, varscan2
- SRCAP | c.5617C>G p.R1873G | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs766102471, COSV52682566, COSV99349456; called by muse, mutect2, varscan2
- STAB2 | c.4396G>A p.G1466R | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs772354918, COSV66348545; called by muse, mutect2, varscan2
- STAMBP | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.925); catalogued as COSV59898535; called by muse, mutect2, varscan2
- SYNE1 | c.14884G>T p.D4962Y (on ENST00000367255 / NM_182961.4; = p.D4891Y on NM_033071.3) | Missense Mutation (SNP) | VAF 48/437 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV55126564; called by muse, mutect2, varscan2
- TAF9B | c.506C>A p.P169Q | Missense Mutation (SNP) | VAF 57/536 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV100540787; called by muse, mutect2, varscan2
- TBC1D7 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV58245234; called by muse, mutect2
- TCHHL1 | c.2194del p.L732Sfs*11 | Frame Shift Del (DEL) | VAF 34/338 reads (10%) | catalogued as COSV64285206; called by mutect2, pindel, varscan2
- TGFB1I1 | c.239C>T p.S80F (on ENST00000394863 / NM_001042454.3; = p.S63F on NM_015927.4) | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.972); catalogued as rs1388865618, COSV62359366; called by muse, mutect2
- TGIF2LX | c.391C>A p.H131N | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV52213346, COSV99033344; called by muse, mutect2, varscan2
- TGIF2LX | c.392A>T p.H131L | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV52215413; called by muse, mutect2, varscan2
- TGM4 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV56097059; called by muse, mutect2, varscan2
- THAP12 | c.1855A>T p.T619S | Missense Mutation (SNP) | VAF 48/352 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV52613620; called by muse, mutect2, varscan2
- TMEM140 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as rs1479668874, COSV51965719, COSV51967762; called by muse, mutect2, varscan2
- TMEM185A | c.470C>A p.A157D | Missense Mutation (SNP) | VAF 5/126 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV57560722; called by muse, mutect2
- TNKS1BP1 | c.4655C>T p.S1552F | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.281); catalogued as rs756039520, COSV64102997; called by muse, mutect2, varscan2
- TNR | c.1747_1748insT p.S583Mfs*29 | Frame Shift Ins (INS) | VAF 25/197 reads (13%) | catalogued as COSV99692144; called by mutect2, pindel, varscan2
- TPO | c.2543C>A p.T848N | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV61112888; called by muse, mutect2, varscan2
- TPRA1 | c.406G>T p.G136C | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV56162159; called by muse, mutect2, varscan2
- TRAPPC9 | c.1493A>G p.Q498R | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.869); catalogued as COSV66911212; called by muse, mutect2, varscan2
- TRIM39 | c.1245C>G p.S415R | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.066); catalogued as COSV100935949; called by muse, mutect2, varscan2
- TRPC5 | c.2064C>A p.D688E | Missense Mutation (SNP) | VAF 48/294 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53304723; called by muse, mutect2, varscan2
- TTC4 | c.1123A>C p.K375Q | Missense Mutation (SNP) | VAF 45/270 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV64885425; called by muse, mutect2, varscan2
- TTF2 | c.2312A>G p.N771S | Missense Mutation (SNP) | VAF 33/258 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65634024; called by muse, mutect2, varscan2
- TTN | c.88379C>A p.P29460H (on ENST00000591111; = p.P22036H on NM_003319.4) | Missense Mutation (SNP) | VAF 48/282 reads (17%) | PolyPhen probably damaging (0.988); catalogued as COSV60403906; called by muse, mutect2, varscan2
- TTN | c.85558C>A p.P28520T (on ENST00000591111; = p.P21096T on NM_003319.4) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | PolyPhen probably damaging (0.999); catalogued as COSV60403950; called by muse, mutect2, varscan2
- TTN | c.43927G>A p.G14643R (on ENST00000591111; = p.G7219R on NM_003319.4) | Missense Mutation (SNP) | VAF 14/90 reads (16%) | PolyPhen probably damaging (1); catalogued as rs368527534; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.42770G>A p.R14257Q (on ENST00000591111; = p.R6833Q on NM_003319.4) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | PolyPhen benign (0.387); catalogued as rs376278449; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.16492G>A p.A5498T (on ENST00000591111; = p.A4571T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/688 reads (12%) | PolyPhen probably damaging (0.998); catalogued as rs987166734, COSV60404097; called by muse, mutect2, varscan2
- TULP4 | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.129); catalogued as rs774514456, COSV65574565, COSV65581917; called by muse, mutect2, varscan2
- TULP4 | c.3493C>T p.R1165* | Nonsense Mutation (SNP) | VAF 22/214 reads (10%) | catalogued as COSV65581925; called by muse, mutect2
- UHRF1BP1 | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV51961395; called by muse, mutect2, varscan2
- UNC79 | c.4841C>T p.S1614L (on ENST00000393151 / NM_001346218.2; = p.S1437L on NM_020818.5) | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.173); catalogued as COSV56416342; called by muse, mutect2, varscan2
- USF3 | c.5528A>G p.Q1843R | Missense Mutation (SNP) | VAF 20/247 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV57078198; called by muse, mutect2
- USP34 | c.1879G>A p.D627N | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.046); catalogued as rs566233715, COSV68408052; called by muse, mutect2, varscan2
- USP42 | c.1290G>C p.Q430H | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as COSV60365127; called by muse, mutect2, varscan2
- WASF1 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV63936286; called by muse, mutect2, varscan2
- WASHC4 | c.2524A>T p.T842S | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as COSV59892866; called by muse, mutect2
- WDR41 | c.1103A>G p.N368S | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV57001128; called by muse, mutect2, varscan2
- WDR49 | c.1507G>T p.V503L (on ENST00000308378 / NM_001366158.1; = p.V844L on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV57719420; called by muse, mutect2, varscan2
- WDR7 | c.2123C>T p.S708F | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as rs765876375, COSV54365536; called by muse, mutect2, varscan2
- WNK1 | c.298C>G p.L100V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0.073); catalogued as COSV60047680; called by muse, mutect2, varscan2
- WWC1 | c.1984A>G p.I662V | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1370804559, COSV54659779; called by muse, mutect2, varscan2
- WWC3 | c.3236G>T p.R1079M | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV66508666; called by muse, mutect2
- WWOX | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.87); PolyPhen benign (0.031); catalogued as rs779872977, COSV68372991; called by muse, mutect2, varscan2
- XIRP2 | c.1380C>G p.D460E (on ENST00000628543; = p.D635E on NM_152381.6) | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54702679, COSV54740007; called by muse, mutect2, varscan2
- ZDHHC1 | c.596A>T p.Y199F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV62215951; called by mutect2, varscan2
- ZFHX4 | c.2362A>T p.S788C | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51500981, COSV99260814; called by muse, mutect2
- ZFP36L1 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV100322426, COSV60547587; called by muse, mutect2, varscan2
- ZMAT1 | c.1861G>C p.V621L | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.396); catalogued as COSV65660370; called by muse, mutect2, varscan2
- ZNF148 | c.2146G>C p.E716Q | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as COSV62308215; called by muse, mutect2, varscan2
- ZNF185 | c.528G>T p.R176= | Splice Region (SNP) | VAF 4/34 reads (12%) | catalogued as COSV59278522; called by muse, mutect2
- ZNF383 | c.733C>G p.Q245E | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.475); catalogued as COSV61940311; called by muse, mutect2, varscan2
- ZNF425 | c.575G>T p.C192F | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV65202962; called by muse, mutect2, varscan2
- ZNF443 | c.1774C>T p.Q592* | Nonsense Mutation (SNP) | VAF 40/220 reads (18%) | catalogued as COSV56894846; called by muse, mutect2, varscan2
- ZNF471 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV57294072; called by muse, mutect2
- ZNF518B | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 56/353 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); catalogued as COSV58725191; called by muse, mutect2, varscan2
- ZNF585A | c.486A>T p.E162D (on ENST00000292841 / NM_001288800.2; = p.E107D on NM_152655.3) | Missense Mutation (SNP) | VAF 35/292 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV53067672; called by muse, mutect2, varscan2
- ZNF600 | c.1055A>T p.H352L | Missense Mutation (SNP) | VAF 34/241 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57745832; called by muse, mutect2, varscan2
- ZNF616 | c.119A>G p.Y40C | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV57513799; called by muse, mutect2, varscan2
- ZNF649 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.084); catalogued as COSV56818335; called by muse, mutect2, varscan2
- ZNF665 | c.329G>A p.G110E (on ENST00000600412; = p.G175E on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/295 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV67218079; called by muse, mutect2, varscan2
- ZNF81 | c.1567G>C p.E523Q | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58578957; called by muse, mutect2, varscan2
- ZPR1 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV57065565; called by muse, mutect2, varscan2
- ZRANB1 | c.458G>A p.W153* | Nonsense Mutation (SNP) | VAF 59/249 reads (24%) | catalogued as COSV62844247; called by muse, mutect2, varscan2
- ADCY2 | c.362del p.G121Dfs*75 | Frame Shift Del (DEL) | VAF 58/243 reads (24%) | called by mutect2, pindel
- ATP9B | c.3190del p.T1064Rfs*5 | Frame Shift Del (DEL) | VAF 8/77 reads (10%) | called by mutect2, varscan2
- IGKV6D-21 | c.235T>G p.S79A | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.021); called by muse, mutect2
- MAGEA4 | c.806_807del p.R269Lfs*2 | Frame Shift Del (DEL) | VAF 37/242 reads (15%) | called by pindel, varscan2
- STK10 | c.1403del p.G468Afs*41 | Frame Shift Del (DEL) | VAF 34/117 reads (29%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.92G>C p.R31T | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.465); called by muse, mutect2
- SUPT20HL1 | c.93G>T p.R31S | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.099); called by muse, mutect2
- TRHDE | c.2686G>A p.D896N | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.038); called by muse, mutect2
- AC100868.1 | c.1548G>A p.V516= | Silent (SNP) | VAF 9/211 reads (4%) | catalogued as COSV51851110; called by muse, mutect2
- ACTA1 | c.69C>T p.F23= | Silent (SNP) | VAF 35/176 reads (20%) | catalogued as rs1339913000, COSV64202957; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADGRG2 | c.2037C>T p.F679= (on ENST00000379869 / NM_001079858.3; = p.F676= on NM_005756.4) | Silent (SNP) | VAF 16/165 reads (10%) | catalogued as rs780969624, COSV61341876; called by muse, mutect2
- AP1B1 | c.1368G>T p.A456= | Silent (SNP) | VAF 33/187 reads (18%) | catalogued as COSV100434899; called by muse, mutect2, varscan2
- APEX2 | c.279G>T p.V93= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV66624592; called by muse, varscan2
- B4GALT4 | c.699G>T p.G233= | Silent (SNP) | VAF 20/183 reads (11%) | catalogued as COSV100785862; called by muse, mutect2, varscan2
- C20orf85 | c.408G>C p.V136= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs764643021, COSV64520033; called by muse, mutect2, varscan2
- CCDC88C | c.1056G>A p.L352= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV66234840, COSV66242558; called by muse, mutect2, varscan2
- CDH16 | c.1992C>A p.A664= | Silent (SNP) | VAF 32/138 reads (23%) | catalogued as COSV55340277; called by muse, mutect2, varscan2
- CLUAP1 | c.873C>T p.L291= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs865793149, COSV58895339; called by muse, mutect2, varscan2
- CMBL | c.333T>C p.S111= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV56985613; called by muse, mutect2, varscan2
- CNTNAP5 | c.3201G>T p.L1067= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as COSV70516881; called by muse, mutect2
- COG5 | c.1113G>A p.S371= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as rs768870825, COSV51745306; called by muse, mutect2, varscan2
- COL12A1 | c.6735A>G p.G2245= | Silent (SNP) | VAF 28/152 reads (18%) | catalogued as COSV59391951; called by muse, mutect2, varscan2
- COL12A1 | c.2334A>G p.T778= | Silent (SNP) | VAF 112/768 reads (15%) | catalogued as COSV59410294; called by muse, mutect2, varscan2
- COL22A1 | c.4779T>A p.P1593= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV57364890; called by muse, mutect2
- CPA3 | c.93C>A p.P31= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV99936578; called by muse, mutect2
- CXorf66 | c.429A>G p.L143= | Silent (SNP) | VAF 68/650 reads (10%) | catalogued as COSV65169892; called by muse, mutect2, varscan2
- CYP2D6 | c.1209G>A p.L403= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs1221208809, COSV100637408, COSV62245854; called by muse, mutect2, varscan2
- DIPK2B | c.909G>T p.G303= | Silent (SNP) | VAF 8/101 reads (8%) | catalogued as COSV67641818; called by muse, mutect2
- DMBT1 | c.7503C>A p.S2501= (on ENST00000338354 / NM_001377530.1; = p.S1744= on NM_004406.3) | Silent (SNP) | VAF 43/232 reads (19%) | catalogued as COSV57566893; called by muse, mutect2, varscan2
- DNAH1 | c.5412C>T p.I1804= | Silent (SNP) | VAF 29/122 reads (24%) | catalogued as rs771985542, COSV70229094; ClinVar: likely benign; called by muse, mutect2, varscan2
- DVL2 | c.1360C>T p.L454= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV50040115; called by muse, mutect2, varscan2
- ELOVL3 | c.207C>G p.L69= | Silent (SNP) | VAF 30/278 reads (11%) | catalogued as rs753191554, COSV64175139; called by muse, mutect2, varscan2
- EPHB1 | c.726G>A p.G242= | Silent (SNP) | VAF 51/364 reads (14%) | catalogued as COSV67673498; called by muse, mutect2, varscan2
- ERVW-1 | c.45C>A p.P15= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as COSV101423811; called by muse, varscan2
- FAM47A | c.1449C>G p.P483= | Silent (SNP) | VAF 23/136 reads (17%) | catalogued as COSV60500368; called by muse, varscan2
- FLOT1 | c.681C>G p.V227= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as COSV52544718; called by muse, mutect2, varscan2
- GABRQ | c.561G>T p.L187= | Silent (SNP) | VAF 22/276 reads (8%) | catalogued as COSV100941203, COSV64784308; called by muse, mutect2
- GDF2 | c.369A>C p.T123= | Silent (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- GHR | c.1161C>T p.T387= | Silent (SNP) | VAF 48/317 reads (15%) | catalogued as COSV50135973; called by muse, mutect2, varscan2
- GOPC | c.645A>C p.A215= | Silent (SNP) | VAF 30/169 reads (18%) | catalogued as COSV50005145; called by muse, mutect2, varscan2
- HECW1 | c.1638C>A p.I546= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as rs761337818, COSV67824478, COSV67841869; called by muse, mutect2, varscan2
- HOXC12 | c.243C>T p.R81= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV54535834; called by muse, mutect2
- HSD3B2 | c.297C>T p.V99= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV65594207; called by muse, mutect2, varscan2
- HUWE1 | c.4383G>T p.V1461= | Silent (SNP) | VAF 20/200 reads (10%) | catalogued as COSV53367030; called by muse, mutect2
- INA | c.330G>A p.E110= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV63976704; called by muse, mutect2, varscan2
- IQGAP1 | c.3906C>T p.I1302= | Silent (SNP) | VAF 23/173 reads (13%) | catalogued as COSV51592312; called by muse, mutect2, varscan2
- KANSL1L | c.2568T>G p.A856= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV55998058; called by muse, mutect2, varscan2
- KIAA0100 | c.873C>G p.S291= | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as COSV66497069; called by muse, mutect2, varscan2
- KIFC2 | c.1816C>T p.L606= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs761166379, COSV56763313; called by muse, mutect2, varscan2
- KMO | c.444G>A p.V148= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV63810893; called by muse, mutect2
- LRP1B | c.12312T>C p.N4104= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV67283726; called by muse, mutect2
- LRP1B | c.10240T>C p.L3414= | Silent (SNP) | VAF 35/248 reads (14%) | catalogued as COSV67263549; called by muse, mutect2, varscan2
- LRRTM1 | c.456C>A p.L152= | Silent (SNP) | VAF 23/129 reads (18%) | catalogued as COSV54447734; called by muse, mutect2, varscan2
- MAEL | c.684G>A p.K228= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs753675290, COSV63112681; called by muse, mutect2, varscan2
- MTMR9 | c.897G>A p.L299= | Silent (SNP) | VAF 15/112 reads (13%) | catalogued as COSV55315779; called by muse, mutect2, varscan2
- MUC16 | c.36270C>T p.D12090= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV67500626; called by muse, mutect2, varscan2
- MUC16 | c.8166C>A p.L2722= | Silent (SNP) | VAF 21/151 reads (14%) | catalogued as rs370245414; called by muse, mutect2, varscan2
- MYOD1 | c.351C>A p.R117= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV51453495, COSV51456054; called by muse, mutect2, varscan2
- NCAM2 | c.2274T>A p.A758= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as COSV53108393, COSV99523857; called by muse, mutect2, varscan2
- NDUFS8 | c.180G>T p.L60= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as COSV50292059; called by muse, mutect2, varscan2
- NEFH | c.1260C>T p.F420= | Silent (SNP) | VAF 34/180 reads (19%) | catalogued as COSV60221318; called by muse, mutect2, varscan2
- NLRP3 | c.1107G>T p.L369= | Silent (SNP) | VAF 19/167 reads (11%) | catalogued as COSV100276152, COSV100276817; called by muse, mutect2, varscan2
- NRXN1 | c.2733C>T p.T911= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV58500555; called by muse, mutect2, varscan2
- OR10G3 | c.870T>C p.T290= | Silent (SNP) | VAF 23/139 reads (17%) | catalogued as COSV57811344; called by muse, mutect2, varscan2
- OR10G8 | c.840C>A p.P280= | Silent (SNP) | VAF 27/197 reads (14%) | catalogued as COSV101461897; called by muse, mutect2, varscan2
- OR2W3 | c.111G>T p.L37= | Silent (SNP) | VAF 33/233 reads (14%) | catalogued as COSV64458267; called by muse, mutect2, varscan2
- OR7A10 | c.669C>T p.S223= | Silent (SNP) | VAF 9/95 reads (9%) | catalogued as COSV50166979; called by muse, mutect2, varscan2
- OR8H1 | c.696A>G p.G232= | Silent (SNP) | VAF 23/201 reads (11%) | catalogued as COSV57296261; called by muse, mutect2, varscan2
- OR8I2 | c.804C>A p.T268= | Silent (SNP) | VAF 25/188 reads (13%) | catalogued as COSV56168871, COSV56170992; called by muse, mutect2, varscan2
- PAPPA | c.4080C>A p.A1360= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as COSV60293722; called by muse, mutect2, varscan2
- PCDHGB6 | c.1851C>T p.F617= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV54051098; called by muse, mutect2, varscan2
- PCSK9 | c.780G>T p.T260= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV100135655, COSV56161518; called by muse, mutect2, varscan2
- PKNOX2 | c.144C>A p.P48= | Silent (SNP) | VAF 20/135 reads (15%) | catalogued as COSV100022120, COSV53549804; called by muse, mutect2, varscan2
- PLCXD3 | c.477C>G p.V159= | Silent (SNP) | VAF 46/415 reads (11%) | catalogued as COSV100125825, COSV60620290; called by muse, mutect2, varscan2
- PLEKHB2 | c.495G>T p.G165= (on ENST00000409279; = p.G164= on NM_017958.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV52178651; called by muse, mutect2, varscan2
- PLS1 | c.996G>C p.L332= | Silent (SNP) | VAF 8/134 reads (6%) | catalogued as COSV61834461, COSV61835788; called by muse, mutect2
- QPCTL | c.996C>G p.L332= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs140632651, COSV50005057; called by muse, mutect2, varscan2
- QPCTL | c.1047C>G p.V349= | Silent (SNP) | VAF 42/261 reads (16%) | catalogued as COSV50005068; called by muse, mutect2, varscan2
- RAB3C | c.138T>C p.F46= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV51443474; called by muse, mutect2, varscan2
- RNPEPL1 | c.1533C>G p.L511= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV54374306; called by muse, mutect2, varscan2
- RRP8 | c.729A>T p.A243= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV54450982; called by muse, mutect2, varscan2
- SAGE1 | c.1701G>A p.P567= | Silent (SNP) | VAF 39/336 reads (12%) | catalogued as rs782344378, COSV61019064; called by muse, mutect2, varscan2
- SEMA3C | c.1749A>G p.V583= | Silent (SNP) | VAF 19/121 reads (16%) | catalogued as rs943447253, COSV54857773; called by muse, mutect2, varscan2
- SHISAL1 | c.45C>T p.L15= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV66989024; called by muse, mutect2, varscan2
- SLC22A6 | c.1044C>A p.A348= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV64561318; called by muse, mutect2
- SLC4A11 | c.66T>C p.A22= | Silent (SNP) | VAF 42/233 reads (18%) | catalogued as COSV66264431; called by muse, mutect2, varscan2
- SLCO6A1 | c.471G>T p.L157= | Silent (SNP) | VAF 24/165 reads (15%) | catalogued as COSV65815711; called by muse, mutect2, varscan2
- SLITRK3 | c.2808C>A p.L936= | Silent (SNP) | VAF 49/376 reads (13%) | catalogued as COSV53854412; called by muse, mutect2, varscan2
- SND1 | c.2403C>T p.I801= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV61250681; called by muse, mutect2, varscan2
- SPESP1 | c.624A>T p.I208= | Silent (SNP) | VAF 46/218 reads (21%) | catalogued as COSV52997427; called by muse, mutect2, varscan2
- TMEM120B | c.132C>T p.S44= | Silent (SNP) | VAF 16/131 reads (12%) | catalogued as COSV61186401; called by muse, mutect2, varscan2
- TMEM185A | c.471C>A p.A157= | Silent (SNP) | VAF 5/127 reads (4%) | catalogued as COSV57560715; called by muse, mutect2
- TMTC1 | c.1506G>T p.A502= (on ENST00000539277 / NM_001193451.2; = p.A394= on NM_175861.3) | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV55488682, COSV55495500; called by muse, mutect2, varscan2
- TRPC5 | c.330C>G p.G110= | Silent (SNP) | VAF 56/287 reads (20%) | catalogued as COSV53287553, COSV53304731; called by muse, mutect2, varscan2
- TTYH2 | c.867C>T p.I289= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV53914102; called by muse, mutect2, varscan2
- VIL1 | c.1413T>C p.N471= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV50300945; called by muse, mutect2, varscan2
- ZNF804A | c.1080C>A p.S360= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV56475348; called by muse, mutect2
- AC024598.1 | c.1130-831G>T | Intron (SNP) | VAF 24/127 reads (19%) | catalogued as COSV60825036; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81157030 G>A | 3'Flank (SNP) | VAF 8/23 reads (35%) | catalogued as rs532290320; called by muse, mutect2
- AL353804.6 | chrX:73827094 G>T | 3'Flank (SNP) | VAF 43/305 reads (14%) | called by muse, mutect2, varscan2
- CASTOR3 | n.430A>G | RNA (SNP) | VAF 29/232 reads (13%) | catalogued as COSV52783050; called by muse, mutect2, varscan2
- CCN6 | c.-23-29G>C | Intron (SNP) | VAF 51/334 reads (15%) | catalogued as COSV100037257; called by muse, mutect2, varscan2
- EIF4G1 | c.147+516del | Intron (DEL) | VAF 53/373 reads (14%) | called by mutect2, pindel, varscan2
- HS6ST2 | c.948-40035C>A | Intron (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100897529; called by muse, mutect2, varscan2
- MFRP | chr11:119345536 C>A | 5'Flank (SNP) | VAF 15/115 reads (13%) | catalogued as COSV64129509; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.809C>A | RNA (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- MIR1202 | n.51C>A | RNA (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- OR3A4P | n.1294C>T | RNA (SNP) | VAF 28/128 reads (22%) | catalogued as rs1254768197; called by muse, mutect2, varscan2
- PHACTR1 | c.251-119582C>G | Intron (SNP) | VAF 10/94 reads (11%) | catalogued as COSV100279246; called by muse, mutect2, varscan2
- PLCB4 | c.*6C>A | 3'UTR (SNP) | VAF 7/46 reads (15%) | catalogued as COSV53805169; called by muse, mutect2, varscan2
- PRR12 | chr19:49594710 A>T | 5'Flank (SNP) | VAF 7/33 reads (21%) | catalogued as COSV55872025; called by muse, mutect2, varscan2
- RTL1 | c.-148-4487G>C | Intron (SNP) | VAF 20/109 reads (18%) | called by muse, mutect2, varscan2
- UNC5D | c.104-4798C>G | Intron (SNP) | VAF 7/121 reads (6%) | catalogued as COSV99775461, COSV99779590; called by muse, mutect2
- XIRP2 | c.*676G>A | 3'UTR (SNP) | VAF 8/74 reads (11%) | catalogued as COSV54745339, COSV99748893; called by muse, mutect2
